Somatic mutation profile of tumor specimen 0DIPL0 from CCDI case PBBVZC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (813 days).
Specimen 0DIPL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50d156fe-12ea-4fc3-9891-86d3e4dd4530.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc725d04-c277-4d34-aae2-b14ce453d6d5

The open-access MAF lists 26 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 7, RNA 3, 3'UTR 2, Silent 2, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 355/830 reads (43%) | catalogued as COSV63660698; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by mutect2, varscan2
- SYNPO2 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 36/700 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318271838, COSV61118007; called by muse, mutect2
- HEPH | c.920T>C p.F307S (on ENST00000343002; = p.F40S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/924 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 78/1493 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MOAP1 | c.300T>A p.N100K | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.164); called by muse, mutect2
- MPHOSPH9 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 22/606 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MPPED2 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 122/511 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.10415C>A p.T3472K | Missense Mutation (SNP) | VAF 221/569 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 82/1422 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ACSM2A | c.285C>T p.N95= (on ENST00000219054; = p.N16= on NM_001308169.2) | Silent (SNP) | VAF 163/1024 reads (16%) | catalogued as rs761252604, COSV99525936; called by muse, mutect2, varscan2
- ACSM2B | c.285C>T p.N95= | Silent (SNP) | VAF 96/242 reads (40%) | catalogued as rs766528681; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 60/575 reads (10%) | called by muse, varscan2
- EGFR | c.2469+98A>G | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 18/259 reads (7%) | called by muse, mutect2
- GOSR1 | c.152+44A>T | Intron (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- KCNK10 | c.38-7280C>T | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 28/223 reads (13%) | called by muse, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 28/214 reads (13%) | catalogued as rs768118261; called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 36/487 reads (7%) | catalogued as rs1415560984; called by mutect2, varscan2
- MYCBPAP | c.-9G>C | 5'UTR (SNP) | VAF 39/273 reads (14%) | catalogued as rs747485826; called by muse, mutect2, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- RPL31P35 | n.355C>G | RNA (SNP) | VAF 11/240 reads (5%) | called by muse, mutect2
- SLC2A5 | c.571+231G>A | Intron (SNP) | VAF 24/56 reads (43%) | called by mutect2, varscan2
- UNK | c.*71del | 3'UTR (DEL) | VAF 13/168 reads (8%) | called by muse*, mutect2
- WTAP | c.87-50T>A | Intron (SNP) | VAF 11/149 reads (7%) | called by mutect2, varscan2
